CCDI case PBBXEL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/9e834bae-b8b4-44e9-a2d7-f9d798fb491a

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 12.6 years (4,590 days).

Biospecimens (3 samples)
- Sample 0DJM8L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJM8R: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJM95: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
